Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7428, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7428-01A (Primary Tumor).

[page 1 of 3]
SUPPLEMENTAL REPORT 2

COMMENT:

Decalcified sections from the right maxillectomy showed moderately differentiated squamous cell carcinoma infiltrating bone.

SUPPLEMENTAL REPORT

DIAGNOSIS:

(K) PTERYGOID:

Decalcified sections show skeletal muscle and bone, no tumor seen.

DIAGNOSIS

- (A) RIGHT SUPRAHYOID NECK DISSECTION:
METASTATIC SQUAMOUS CARCINOMA IN 2 OF 10 LYMPH NODES
(12.0 MM).
Submandibular gland, no tumor present.
- (B) MUSCLE FROM NASAL ALA:
Muscle, fibrosis and minor salivary gland tissue,
no tumor present.
- (C) PTERYGOID MARGIN:
INVASIVE SQUAMOUS CARCINOMA IN CONNECTIVE TISSUE.
- (D) RIGHT MIDDLE TURBINATE:
Pending decalcification.

[page 2 of 3]
- (E) RIGHT MAXILLECTOMY:
DEEPLY INVASIVE SQUAMOUS CARCINOMA, MODERATELY DIFFERENTIATED
EXTENDING TO BONE AND SOFT TISSUE.
- (F) RIGHT SOFT PALATE:
Skeletal muscle, adipose tissue and minor salivary gland
tissue, no tumor present.
- (G) PTERYGOID:
INVASIVE SQUAMOUS CARCINOMA IN CONNECTIVE TISSUE AND
SKELETAL MUSCLE.
- (H) INFRAORBITAL NERVE:
Nerve with fibrosis and inflammation, no tumor present.
- (I) BUCCAL FAT:
Adipose tissue and skeletal muscle with inflammation,
no tumor present.
- (J) POSTERIOR FLOOR ETHMOID:
Sinonasal mucosa and bone, no tumor present.
- (K) PTERYGOID:
Fibroconnective tissue, skeletal muscle and bone,
no tumor present.
- (L) PTERYGOID PALATE:
INVASIVE SQUAMOUS CARCINOMA IN FIBROCONNECTIVE TISSUE,
SKELETAL MUSCLE AND MUCOSA.
- (M) RIGHT SOFT PALATE:
Skeletal muscle and fibrosis, no tumor present.
- (N) NEW PTERYGOID MARGIN:
Fibrosis and inflammation, no tumor present.
- (O) TEETH:
Carious teeth, gross only.

GROSS DESCRIPTION

(A) RIGHT SUPRAHYOID NECK DISSECTION - A 9.8 x 3.2 x 2.5 cm neck dissection which includes a 4.8 x 2.8 x 2.3 cm submandibular gland. A 2.7 cm grossly positive lymph node is present. Multiple other lymph nodes are found with no definite tumor.

SECTION CODE: A1, representative section of positive node; A2, submandibular gland; A3-A5, one lymph node trisected in three cassettes; A6-A14, one bisected lymph node in each cassette; A15, one lymph node. RL/mgd

(B) MUSCLE FROM NASAL ALA (INK TRUE MARGIN) - A segment of red-brown soft tissue (1.2 x 0.8 x 0.4 cm) showing cautery effect and ink on the designated true margin. Entirely submitted en face for frozen section, B.

*FS/DX: FIBROSIS, NO TUMOR PRESENT.

(C) PTERYGOID MARGIN - Four fragments of tan-red fibrous tissue measuring 1.5 x 1.3 x 0.4 cm in aggregate.

SECTION CODE: C, entire specimen for frozen section.

*FS/DX: INVASIVE SQUAMOUS CARCINOMA.

[page 3 of 3]
[REDACTED]

(D) RIGHT MIDDLE TURBINATE - A 3.6 x 1.2 x 0.7 cm piece of new tan mucosa and underlying bone, consistent with turbinate. Mucosa shows focal congestion. No tumor is seen.

SECTION CODE: D1-D3, entire specimen, after decalcification. [REDACTED]

(E) RIGHT MAXILLECTOMY - A partial maxillectomy 6.0 x 5.0 x 3.0 cm tan ulcerated and infiltrative 4.0 x 2.0 x 3.5 cm slightly firm mass extending into bone is noted. Representative sections are submitted E1-E18. [REDACTED]

(F) RIGHT SOFT PALATE - A 1.7 x 1.2 x 0.8 cm portion of soft smooth tan tissue.

SECTION CODE: F1-F2, entire specimen. [REDACTED]

(G) PTERYGOID - A 0.8 x 0.3 x 0.3 cm piece of fibrous tan tissue.

SECTION CODE: G, entire specimen. [REDACTED]

(J) POSTERIOR ETHMOID FLOOR - A 0.9 x 0.5 x 0.3 cm friable pink-tan soft tissue fragment. Entirely submitted as G. [REDACTED]

(H) INFRAORBITAL NERVE - A piece of connective tissue 0.4 cm long x 0.2 cm in diameter. Entirely submitted for frozen section in one cassette. [REDACTED]

*FS/DX: FIBROSIS AND INFLAMMATION, NO TUMOR PRESENT. [REDACTED]

(I) BUCCAL FAT - A 4.3 x 1.7 x 0.9 cm portion of adipose tissue. No tumor is seen.

SECTION CODE: A I1-I2, representative sections. [REDACTED]

(J) POSTERIOR ETHMOID FLOOR - A 0.9 x 0.5 x 0.3 cm friable pink-tan soft tissue fragment. Entirely submitted as G. [REDACTED]

(K) PTERYGOID - A 1.5 x 0.9 x 0.9 cm irregularly shaped segment of pink-tan focally cauterized soft tissue and bone. The soft tissue is entirely submitted as K. The bone is submitted to the Bone Laboratory for additional processing. [REDACTED]

(L) PTERYGOID PALATE - A 2.8 x 2.0 x 1.0 cm aggregate of pink-tan soft tissue fragments and translucent thin bone. The soft tissue fragments are entirely submitted as L1 and L2; the bone is submitted to the Bone Laboratory for additional processing. [REDACTED]

(M) RIGHT SOFT PALATE - A 2.4 x 0.4 cm strip of mucosa with 0.3 cm of underlying tissue. No lesion is seen.

INKING CODE: Blue-lateral.

SECTION CODE: M, entire specimen for frozen section. [REDACTED]

*FS/DX: SKELETAL MUSCLE AND FIBROSIS, NO TUMOR PRESENT. [REDACTED]

(N) NEW PTERYGOID MARGIN - Two fragments of tan-red fibrous tissue, each measuring approximately 1.0 x 0.8 x 0.4 cm.

SECTION CODE: N1, N2, entire specimen for frozen section. [REDACTED]

*FS/DX: FIBROSIS, NO TUMOR PRESENT. [REDACTED]

(O) TEETH - Sixteen teeth and fragments of teeth with gross caries. Specimen submitted for gross examination only. [REDACTED]

SNOMED CODES

M-80703 M-80706 T-22000 T-C4200

Source: NCI Genomic Data Commons file 3cbcb291-b992-416e-9c98-00b65d50c4d1 (TCGA-CV-7428.8B051043-6FEE-4C13-9791-95ED686EE015.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).